Gene-level copy-number profile of tumor specimen SM-JU356 from CPTAC case C685110, project CPTAC-3 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Intraductal carcinoma, NOS; Tissue or organ of origin: Breast, NOS.
Specimen SM-JU356: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 869ff40e-bad0-4687-88f3-0e588f09601c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105277 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/e93e4a3e-7550-4bae-9c01-eb87cd347344

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 22,626; copy number 2: 28,893; copy number 3: 5,371; copy number 4: 1,384; copy number 5: 39; copy number 6: 10.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:161,581,339–161,678,654, 6 genes (within-gene range 0–2): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr5:125,265,528–125,265,651, 1 gene: HMGB1P22.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr7:76,609,986–76,627,261, 1 gene (within-gene range 0–1): POMZP3.
- chr8:7,170,550–7,191,563, 2 genes: SNRPCP15, RPS3AP33.
- chr8:108,871,128–109,063,417, 1 gene: AC104248.1.
- chr9:14,081,843–14,910,995, 14 genes: NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:14,921,337–15,019,729, 2 genes (within-gene range 0–1): LDHAP4, AL592293.1.
- chr11:112,967–186,136, 5 genes (within-gene range 0–1): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr15:21,010,494–21,260,147, 13 genes: IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16, NBEAP4.
- chr15:21,980,277–21,981,245, 1 gene: OR11J6P.
- chr15:101,903,154–101,979,093, 10 genes: AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr18:7,741,310–7,754,831, 1 gene (within-gene range 0–1): AP000897.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,436,359–248,498,649, 6 genes, copy number 5: OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P.
- chr1:248,810,446–248,937,043, 8 genes, copy number 5: SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:231,388,976–231,401,164, 2 genes, copy number 5: AC017104.1, B3GNT7.
- chr7:2,906,142–3,043,867, 1 gene, copy number 5 (within-gene range 3–5): CARD11.
- chr7:2,999,094–3,302,452, 5 genes, copy number 5 (within-gene range 3–5): RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1.
- chr7:37,585,500–38,025,695, 7 genes, copy number 5–6: NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4.
- chr7:40,964,667–41,133,507, 2 genes, copy number 5: LINC01450, LINC01449.
- chr11:107,502,727–108,121,684, 14 genes, copy number 5 (within-gene range 4–5): ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1.
- chr17:73,207,353–73,262,352, 4 genes, copy number 6 (within-gene range 4–6): FAM104A, C17orf80, AC087301.1, CPSF4L.

Autosomal genes at a single copy (total copy number 1): 21,940. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
